Somatic mutation profile of tumor specimen C3L-00608-01 (aliquot CPT0390480006) from CPTAC case C3L-00608, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 61.5 years (22,445 days).
Specimen C3L-00608-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6130c94c-c0ee-45d8-85d6-6db60b25273b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00608-31 (Blood Derived Normal), aliquot CPT0390540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bad87943-d2b2-4b6e-bf78-44c82869c592

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO1A | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100270484; called by muse, mutect2
- NPR2 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 67/600 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as rs202085166; called by muse, mutect2, varscan2
- OR51Q1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs866002052, COSV56179996; called by muse, mutect2, varscan2
- PENK | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs367716870; called by muse, mutect2, varscan2
- SLC12A8 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.131); catalogued as COSV58868440; called by muse, mutect2, varscan2
- ZNF469 | c.7754G>A p.R2585Q (on ENST00000437464; = p.R2613Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 94/755 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370285147; called by muse, mutect2, varscan2
- AGGF1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DDX60 | c.4441G>T p.E1481* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FBN2 | c.6238C>A p.Q2080K | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- HASPIN | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYAL4 | c.1309T>G p.C437G | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- MAGEE1 | c.2410G>C p.V804L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2
- ADAT3 | c.696C>T p.C232= | Silent (SNP) | VAF 98/390 reads (25%) | catalogued as rs1429794508; called by muse, mutect2, varscan2
- AHNAK2 | c.10923C>T p.P3641= | Silent (SNP) | VAF 33/644 reads (5%) | called by muse, mutect2
- CARM1 | c.186C>T p.A62= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs1333668046; called by muse, mutect2
- OR7A17 | c.861C>A p.P287= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as COSV59415424; called by muse, mutect2, varscan2
- MACF1 | c.15832-9398C>T | Intron (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
